Gene-level copy-number profile of tumor specimen AP-52RG-3C from APOLLO case AP-52RG, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2.
Specimen AP-52RG-3C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6adb27ec-cbe0-4e78-bc4f-bfa30faaa964.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-52RG-PM (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/84ef5a56-07d5-4be4-abb2-0ba725b025a0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 2,236; copy number 2: 23,341; copy number 3: 27,558; copy number 4: 4,584; copy number 5: 363; copy number 6: 156; copy number 7: 12; copy number 8: 34; copy number 9: 37; copy number 10: 1; copy number 11: 10; copy number 12: 10.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:134,196,333–134,201,789, 1 gene: PABPC4L.
- chr6:391,752–1,528,911, 22 genes: IRF4, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2.
- chr9:212,824–1,333,953, 21 genes: DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279.
- chr13:18,467,172–18,667,221, 6 genes: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 104 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:4,135,423–6,007,605, 32 genes, copy number 7–10 (within-gene range 2–10): AL136309.3, ECI2-DT, AL136309.2, AL136309.1, AL162718.1, AL159166.1, RNA5SP202, LINC02533, AL133393.1, AL034376.1, KU-MEL-3, PSMC1P11, CDYL, AL356747.1, CDYL-AS1, AL359643.1, RPP40, LYRM4-AS1, AL359643.2, AL139094.1, PPP1R3G, LYRM4, MIR3691, AL121978.1, AL021328.1, HNRNPA1P37, AL022097.1, AL136968.2, AL136307.1, RN7SL221P, PKMP5, NRN1.
- chr12:64,186,316–67,132,205, 71 genes, copy number 8–12 (broad region; genes not listed).
- chr12:71,007,773–71,032,083, 1 gene, copy number 7: AC123905.1.

Autosomal genes at a single copy (total copy number 1): 2,236. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
